Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4999, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4999-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

female with left renal mass, h/o ocular melanoma.

TCGA-BP-4999

Specimens Submitted:

1: SP: Kidney, left, partial nephrectomy

DIAGNOSIS:

1. SP: Kidney, left, partial nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 3.5 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

N/A

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not Identified

Lymph Nodes:

Not Identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Gross Description:

1). The specimen is received for frozen section consultation labeled "left renal tumor". It consists of a 6.2 x 6.0 x 5.0 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal a cystic mass with a small yellow solid component, measuring overall 0.5 x 3.5 x 3.0 cm. The clearance from the resection margin is 0.2 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for

Summary of sections:

FSC - frozen section control

T - tumor

M - margin

RS - representative sections

Summary of Sections:

Part 1: SP: Kidney, left, partial nephrectomy

Block	Sect. Site	PCs
1	fsc	1
1	m	1
1	rs	1
4	t	4

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL EPITHELIAL TUMOR. MARGIN IS CLOSE BUT CLEAR.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file e8bcf367-d118-4a34-8680-32708489e826 (TCGA-BP-4999.0D9B13DB-7D38-4D54-96E3-BE5F91FB5CB4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).